Gene-level copy-number profile of tumor specimen ALCH-AE2C-TTP1-A from ALCHEMIST case ALCH-AE2C, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 58.4 years (21,317 days).
Specimen ALCH-AE2C-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ffff248e-dad2-45c9-91f5-b92dd421eeed.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE2C-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/bccfeea1-df6c-4c03-9cd6-1e96883f7a31

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 221; copy number 1: 6,474; copy number 2: 48,679; copy number 3: 3,221; copy number 4: 179; copy number 5: 11; copy number 6: 67; copy number 7: 43; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:44,988,234–44,991,834, 2 genes: PPIAP35, MRPS17P1.
- chr3:87,051,192–87,052,738, 1 gene: PPATP1.
- chr4:13,526,319–13,534,335, 1 gene: LINC01097.
- chr4:128,069,014–128,069,612, 1 gene (within-gene range 0–2): AC099340.1.
- chr5:171,305,980–171,309,777, 1 gene (within-gene range 0–1): AC091980.2.
- chr6:32,032,713–32,041,644, 2 genes (within-gene range 0–2): C4B-AS1, CYP21A2.
- chr6:34,466,061–34,535,229, 1 gene: PACSIN1.
- chr6:42,696,598–42,722,597, 1 gene: PRPH2.
- chr8:142,763,116–142,778,224, 4 genes: AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1.
- chr9:39,154,075–39,160,319, 2 genes (within-gene range 0–1): RBM17P1, AL353729.2.
- chr9:96,385,941–96,418,370, 3 genes: ZNF367, NSA2P7, AL133477.1.
- chr9:133,097,720–133,163,914, 2 genes (within-gene range 0–1): RALGDS, AL162417.1.
- chr10:21,217,891–21,248,095, 2 genes: AL731547.1, LUZP4P1.
- chr14:45,502,742–45,503,140, 1 gene: AL162632.2.
- chr15:41,825,099–41,848,155, 3 genes (within-gene range 0–2): AC020659.2, JMJD7, JMJD7-PLA2G4B.
- chr16:32,475,051–32,478,250, 1 gene: ABCD1P3.
- chr19:14,031,762–14,053,218, 1 gene: IL27RA.
- chr21:36,698,773–36,701,564, 1 gene (within-gene range 0–2): AP000697.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 123 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:180,542,701–183,684,519, 65 genes, copy number 6–7 (broad region; genes not listed).
- chr8:7,256,904–7,290,402, 5 genes, copy number 5: FAM90A15P, FAM90A3P, FAM90A4P, FAM90A13P, FAM90A5P.
- chr8:38,223,957–39,995,248, 40 genes, copy number 6 (within-gene range 2–6): AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4.
- chr16:32,600,299–32,615,639, 1 gene, copy number 6: AC137800.1.
- chr16:32,809,556–32,824,645, 2 genes, copy number 5: AC137761.1, AC137761.2.
- chr16:32,869,985–32,888,874, 3 genes, copy number 5–7: BCAP31P2, SLC6A10P, AC142086.1.
- chr21:44,107,373–44,210,114, 2 genes, copy number 5 (within-gene range 1–8): PWP2, GATD3A.
- chr21:44,172,169–44,194,338, 2 genes, copy number 8: AP001056.2, AP001056.1.
- chr21:44,217,014–44,244,993, 3 genes, copy number 6: ICOSLG, AP001059.2, AP001059.1.

Autosomal genes at a single copy (total copy number 1): 3,817. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
